Gene-level copy-number profile of tumor specimen C3L-05480-03 from CPTAC case C3L-05480, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 61.5 years (22,446 days).
Specimen C3L-05480-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4112d92a-558f-4119-9ba2-eb2733fb4590.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05480-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/5132084c-42e3-4b7f-b124-b1f69f1314af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 59; copy number 1: 1,857; copy number 2: 35,228; copy number 3: 14,226; copy number 4: 7,474; copy number 5: 62; copy number 6: 8.

Homozygous deletions (total copy number 0; autosomes only): 59 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,134–746,106, 22 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1.
- chr9:976,655–2,660,056, 18 genes: DMRT3, RNU6-1073P, H3P29, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1.
- chr9:17,134,982–17,503,923, 2 genes: CNTLN, SAMM50P1.
- chr9:17,589,161–17,591,318, 1 gene (within-gene range 0–3): PABPC1P11.
- chr9:21,802,636–22,128,103, 14 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr16:6,873,899–7,004,112, 2 genes (within-gene range 0–2): RNU6-457P, RNU6-328P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 70 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:107,826,892–107,915,286, 4 genes, copy number 5: RGPD4, AC009963.2, AC009963.1, RPL22P8.
- chr9:68,328,308–69,392,558, 20 genes, copy number 5–6 (within-gene range 4–6): PGM5, PGM5-AS1, AL161457.2, AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1, PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2, BANCR, FAM189A2.
- chr9:97,386,240–99,377,240, 46 genes, copy number 5: AL512590.1, TDRD7, TMOD1, AL162385.1, TSTD2, NCBP1, AL162385.2, XPA, KRT18P13, PTCSC2, AL445531.1, FOXE1, TRMO, Y_RNA, AL499604.1, HEMGN, ANP32B, AL354726.1, RNU6-918P, NANS, TRIM14, Metazoa_SRP, CORO2A, TBC1D2, MIR6854, AL360081.1, GABBR2, SEPTIN7P7, ANKS6, GALNT12, AL136084.1, NME2P3, COL15A1, AL136084.2, TGFBR1, RNA5SP290, AL162427.1, RN7SL794P, ALG2, SEC61B, RN7SKP225, KRT8P11, NAMA, AL137067.2, AL137067.3, AL137067.1.

Autosomal genes at a single copy (total copy number 1): 476. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
